Surgical pathology report (de-identified scan), TCGA case TCGA-W2-A7UY, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Medical College of Wisconsin, specimen TCGA-W2-A7UY-01A (Primary Tumor).

[page 1 of 2]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Entered by

Component Results

SURG PATH FINAL REPORT:

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

A. Right adrenal

Clinical Notes:

Pre-op diagnosis: Pheochromocytoma. Fresh tissue saved for

Diagnosis:

A. Right adrenal:

- Pheochromocytoma.

(Electronically signed by)

Verified:

Gross:

A. The specimen is labeled "right adrenal". Received fresh is a 13.0 x 10.5 x 2.5 cm portion of disrupted yellow-red lobulated fibroadipose tissue. Within this area of disruption is a 7.5 x 3.5 x 3.0 cm adrenal gland. The adrenal gland contains a 4.0 x 3.0 x 3.0 cm mass. The capsule of the mass is stripped due to the disruption of the tissue. The mass exhibits a rough orange-yellow rim with a soft red-brown partially cystic center. The uninvolved adrenal exhibits a thin orange-tan cortical rim with a central tan-brown medulla. The fat history from the adrenal and the gland is 50.1 g. A portion of the tissue is given to Representative sections are submitted as follows:

Cassette Designation:

A1-A5

Nodule

A6-A7

Unremarkable adrenal

ICD-O-3

Pheochromocytoma NOS
8700/0

Site (Right) Adrenal gland NOS
C74.9

JW 10/4/13

[page 2 of 2]
Microscopic:
A histological examination has been performed.

Accession #:

Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time

Entered by

Criteria	lw 9/26/13	No

Source: NCI Genomic Data Commons file 1f1fc70c-6f38-4bbe-9abd-1fb23b03cb09 (TCGA-W2-A7UY.5FD5635C-D9F3-4149-ABB6-C25311D78A65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).